Somatic mutation profile of tumor specimen TCGA-BP-4960-01A (aliquot TCGA-BP-4960-01A-01D-1462-08) from TCGA case TCGA-BP-4960, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 46.8 years (17,099 days).
Specimen TCGA-BP-4960-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a72a1f1-b50b-4977-b778-82ca010aab26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4960-11A (Solid Tissue Normal), aliquot TCGA-BP-4960-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b3911ff-7619-4ac0-8864-8d740af0b0f3

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 45, Silent 15, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 35/75 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913346, CM164440, CM941379, COSV56543253, COSV56550270, COSV56558440, COSV56563690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2818C>G p.L940V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54032149, COSV54035439; called by muse, mutect2, varscan2
- ADAMTS9 | c.3652G>A p.D1218N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV55784009, COSV55789518; called by muse, mutect2, varscan2
- ADGRV1 | c.2960T>G p.V987G | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV67988240; called by muse, mutect2, varscan2
- ATAD1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57757458; called by muse, mutect2
- ATP8A2 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54959476; called by muse, mutect2, varscan2
- BTBD7 | c.2827C>G p.P943A | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58287958; called by muse, mutect2, varscan2
- CERS4 | c.818_820del p.F273del | In Frame Del (DEL) | VAF 32/158 reads (20%) | catalogued as rs781093214; called by pindel, varscan2
- CTNND1 | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.356); catalogued as COSV62384290; called by muse, mutect2, varscan2
- FHOD1 | c.2939T>C p.L980P | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs772896045, COSV50762967; called by muse, mutect2, varscan2
- GCNT1 | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373409583; called by muse, mutect2, varscan2
- GPC4 | c.1537T>G p.Y513D | Missense Mutation (SNP) | VAF 148/239 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV63698407; called by muse, mutect2, varscan2
- GPX8 | c.311T>G p.L104W | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57053812, COSV57058246; called by muse, mutect2, varscan2
- HDGFL1 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57752291; called by muse, mutect2, varscan2
- HSPB11 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52041142; called by muse, mutect2, varscan2
- HTR3A | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55470164; called by muse, mutect2
- KHNYN | c.1198T>A p.W400R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV52161625; called by muse, mutect2, varscan2
- KIF20B | c.5114A>C p.K1705T (on ENST00000371728 / NM_001284259.2; = p.K1665T on NM_016195.4) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV53309671; called by muse, mutect2, varscan2
- LAMA4 | c.2065G>A p.E689K (on ENST00000230538 / NM_001105206.3; = p.E682K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57899504; called by muse, mutect2
- LRIG2 | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63162753; called by muse, mutect2, varscan2
- MAST3 | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs1304191498, COSV53222574; called by muse, mutect2, varscan2
- NEK11 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV53909127; called by muse, mutect2
- NOS2 | c.3164A>G p.Y1055C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58224836; called by muse, mutect2
- NRXN2 | c.1833C>G p.F611L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV55456283; called by muse, mutect2, varscan2
- NUP133 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572643; called by muse, mutect2, varscan2
- NYNRIN | c.4996C>A p.H1666N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as COSV66843259; called by muse, mutect2
- OR6K2 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as COSV62743684; called by muse, mutect2, varscan2
- OXCT1 | c.1172+1G>C p.X391_splice | Splice Site (SNP) | VAF 13/93 reads (14%) | catalogued as COSV52172680; called by muse, mutect2, varscan2
- PCDHA9 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs572249977, COSV65324558; called by muse, mutect2, varscan2
- PGLYRP2 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs372471706; called by mutect2, varscan2
- PGM2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs769078682, COSV67938572; called by mutect2, varscan2
- PPM1J | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58552166; called by muse, mutect2, varscan2
- PRRC2C | c.8417C>A p.P2806Q (on ENST00000367742; = p.P2804Q on NM_015172.4) | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58907511, COSV58915984; called by muse, mutect2, varscan2
- SEC31A | c.2389C>A p.H797N (on ENST00000355196 / NM_001318120.1; = p.H758N on NM_016211.4) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52347201; called by muse, mutect2, varscan2
- SLC1A1 | c.1044C>G p.N348K | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); catalogued as COSV52054492; called by muse, mutect2, varscan2
- TBX19 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1365741516, COSV63197793; called by muse, mutect2, varscan2
- TLN2 | c.7018C>A p.L2340M | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV60885187, COSV60891280; called by muse, mutect2
- TNKS1BP1 | c.5161G>T p.A1721S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64101504; called by muse, mutect2, varscan2
- TNNT1 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV52572239; called by muse, mutect2
- TNR | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765777878, COSV54894042; called by muse, mutect2, varscan2
- TRIM65 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs765174948, COSV53932176; called by muse, mutect2, varscan2
- TRPM3 | c.442G>T p.G148* (on ENST00000357533 / NM_001366142.2; = p.G117* on NM_001007471.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/224 reads (19%) | catalogued as COSV62471678, COSV62474705; called by muse, mutect2, varscan2
- UHRF1 | c.1933G>T p.G645C (on ENST00000612630 / NM_001290050.1; = p.G658C on NM_013282.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53575292; called by muse, mutect2, varscan2
- VARS1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs1156960014, COSV65155347; called by muse, mutect2
- ZDHHC8 | c.1578C>A p.S526R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57711226; called by muse, mutect2, varscan2
- ZNF594 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV68385659; called by muse, mutect2, varscan2
- ADHFE1 | c.449del p.N150Ifs*12 | Frame Shift Del (DEL) | VAF 80/233 reads (34%) | called by mutect2, pindel, varscan2
- ALMS1 | c.8352dup p.V2785Sfs*8 | Frame Shift Ins (INS) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- ASB3 | c.366_371del p.N122_Q124delinsK | In Frame Del (DEL) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- CEACAM4 | c.276_277del p.A93Rfs*39 | Frame Shift Del (DEL) | VAF 47/237 reads (20%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PBRM1 | c.1914del p.K638Nfs*4 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, pindel, varscan2
- RETREG1 | c.1042dup p.S348Ffs*14 (on ENST00000306320 / NM_001034850.2; = p.S207Ffs*14 on NM_019000.4) | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- SELENON | c.993_994del p.F332Rfs*? | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | called by pindel, varscan2
- ACTN1 | c.1857G>C p.T619= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV51989249, COSV51992960, COSV51993749; called by muse, mutect2, varscan2
- ADGRL2 | c.741T>C p.Y247= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV54673613; called by muse, mutect2, varscan2
- CPEB4 | c.1398A>G p.R466= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV54173383; called by muse, mutect2, varscan2
- ITGA11 | c.3483G>A p.L1161= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV59879067; called by muse, mutect2
- LRRIQ3 | c.714G>A p.V238= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV63045626; called by muse, mutect2, varscan2
- MBOAT2 | c.348T>G p.T116= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV60009929; called by muse, mutect2, varscan2
- MCM4 | c.102T>A p.S34= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV50625437; called by muse, mutect2, varscan2
- NLRP6 | c.1677C>T p.I559= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs199706714, COSV56460444; called by muse, mutect2, varscan2
- PARD6B | c.1098T>C p.D366= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs759148478, COSV65404669; called by muse, mutect2, varscan2
- PLG | c.864T>A p.A288= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as COSV51984044; called by muse, mutect2, varscan2
- RCVRN | c.336C>T p.D112= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs764050659, COSV56841753; called by muse, mutect2, varscan2
- SCAF11 | c.1959G>C p.G653= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as COSV65477319; called by muse, mutect2
- SNX14 | c.807T>A p.L269= (on ENST00000314673 / NM_001350535.1; = p.L225= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV59013620; called by muse, mutect2, varscan2
- STRA8 | c.399C>T p.S133= (on ENST00000275764; = p.S111= on NM_182489.2) | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV51961988, COSV99312296; called by muse, mutect2, varscan2
- ZNF395 | c.558T>C p.P186= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV60429248, COSV60430151; called by muse, mutect2, varscan2
